CPTAC case C3L-00156 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6505022e-f2c9-4aa9-9904-27adcfe63f74

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1960; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Endometrium; Age at diagnosis: 56.2 years (20,525 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,776 days (4.9 years); Progression or recurrence: no; Days to last follow up: 1,776 days (4.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.2 cm (a second GDC size field records 6 cm); Lymph nodes tested: 0; Margin status: Uninvolved.

Follow-up (6 entries)
- Days to follow up: 364 days; Disease response: Tumor Free.
- Days to follow up: 671 days (1.8 years); Disease response: Tumor Free.
- Days to follow up: 1,035 days (2.8 years); Disease response: Tumor Free.
- Days to follow up: 1,419 days (3.9 years); Disease response: Tumor Free.
- Days to follow up: 1,776 days (4.9 years); Disease response: Tumor Free.
- Days to follow up: 1,776 days (4.9 years); Disease response: Complete Response.

Other clinical attributes
- Weight: 83 kg; Height: 172.7 cm; BMI: 27.83; Comorbidities: Sleep Apnea; Diabetes treatment type: Insulin.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00156-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 244 mg.
- Sample C3L-00156-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 315 mg; Time between excision and freezing: 22 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00156-22: Section location: Anterior endometrium; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3L-00156-12: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Time between excision and freezing: 22 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00156-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
